Somatic mutation profile of tumor specimen TCGA-75-6212-01A (aliquot TCGA-75-6212-01A-11D-1753-08) from TCGA case TCGA-75-6212, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Invasive micropapillary carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-75-6212-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76e4d4b5-4964-43b7-8008-d160245f5c5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-6212-10A (Blood Derived Normal), aliquot TCGA-75-6212-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/873e2d89-7b01-4e6a-8221-5440fdd0a295

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, In Frame Del 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 24/84 reads (29%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- ADGRE1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs767177184, COSV51678677; called by muse, mutect2, varscan2
- AFF1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.396); catalogued as COSV57122998; called by muse, mutect2, varscan2
- CCDC125 | c.27T>G p.S9R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV101143624; called by muse, mutect2, varscan2
- CHM | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV63303934; called by muse, mutect2, varscan2
- FGA | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57399704; called by muse, mutect2, varscan2
- KIF9 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs780814807, COSV55522864; called by muse, mutect2
- L1CAM | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs200605257, COSV62828942; called by muse, mutect2, varscan2
- MRPL39 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56261833; called by muse, mutect2, varscan2
- NKD1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.526); catalogued as COSV51693742; called by muse, mutect2, varscan2
- SCML4 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV64637522; called by muse, mutect2, varscan2
- SSTR4 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as COSV54799758; called by muse, mutect2, varscan2
- VPS13B | c.9331A>G p.I3111V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754287195, COSV62153785; called by muse, mutect2, varscan2
- ZNF420 | c.1354T>C p.C452R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58495773; called by muse, mutect2, varscan2
- GTF2I | c.393_405del p.T132Yfs*14 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- MAX | c.178_180del p.R60del | In Frame Del (DEL) | VAF 27/56 reads (48%) | called by mutect2, pindel, varscan2
- PHF21B | c.705G>A p.Q235= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV57561314; called by muse, mutect2, varscan2
- SP140L | c.234C>T p.L78= | Silent (SNP) | VAF 41/288 reads (14%) | catalogued as COSV54747215; called by muse, mutect2, varscan2
- TBL1X | c.927C>T p.D309= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs142039049, COSV54276148; called by muse, mutect2, varscan2
- TMPRSS13 | c.789C>T p.C263= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1464186513, COSV70627424; called by muse, mutect2, varscan2
- OBSCN | c.5138-1606G>A | Intron (SNP) | VAF 5/45 reads (11%) | catalogued as rs200651373, COSV99479297; called by muse, mutect2
